Somatic mutation profile of cancer-model specimen HCM-BROD-0019-C25-85A (3D Organoid, passage 20; aliquot HCM-BROD-0019-C25-85A-01D-A80U-36), derived from the primary tumor of HCMI case HCM-BROD-0019-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Tumor grade: G1; Age at diagnosis: 80.6 years (29,434 days).
Specimen HCM-BROD-0019-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 20.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35359d6d-800c-4007-a018-3f1686703e5f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0019-C25-10B (Blood Derived Normal), aliquot HCM-BROD-0019-C25-10B-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8681d73-cdd8-4349-b021-8b5f658cdf8b

The open-access MAF lists 89 somatic variants for this specimen: 64 protein-altering or splice-affecting, 19 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 19, Intron 5, Frame Shift Ins 3, Frame Shift Del 2, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 144/292 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPHP3 | c.3156dup p.S1053Ifs*3 | Frame Shift Ins (INS) | VAF 23/63 reads (37%) | catalogued as rs771215577; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.445del p.S149Pfs*21 | Frame Shift Del (DEL) | VAF 209/292 reads (72%) | catalogued as rs1064793929, COSV52688587, COSV52700895; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BTAF1 | c.5225G>A p.R1742H | Missense Mutation (SNP) | VAF 93/209 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56430044; called by muse, mutect2, varscan2
- C6orf118 | c.704A>T p.D235V | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57812860; called by muse, mutect2, varscan2
- CACNA2D1 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 154/301 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1224350198, COSV62396491; called by muse, mutect2, varscan2
- CACNA2D4 | c.3256C>T p.R1086C | Missense Mutation (SNP) | VAF 243/412 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1446549662, COSV54960579; called by muse, mutect2, varscan2
- CCDC18 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 92/214 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.057); catalogued as rs751071577, COSV58141699; called by muse, mutect2, varscan2
- CFHR3 | c.58G>T p.V20L | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV66401961, COSV66403247; called by muse, mutect2, varscan2
- EGFL6 | c.128A>G p.Y43C | Missense Mutation (SNP) | VAF 114/233 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1569203189; called by muse, mutect2, varscan2
- EXOC4 | c.41T>C p.V14A | Missense Mutation (SNP) | VAF 166/246 reads (67%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs758899475; called by muse, mutect2, varscan2
- GPD1 | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 110/409 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1203823460; called by muse, mutect2, varscan2
- GRIP2 | c.311G>A p.R104Q (on ENST00000619221; = p.R7Q on NM_001080423.4) | Missense Mutation (SNP) | VAF 206/464 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.3); catalogued as rs766011095, COSV56124881; called by muse, varscan2
- HECW1 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 113/238 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs779347290, COSV101223022, COSV67831867; called by muse, mutect2, varscan2
- KAT7 | c.1585C>T p.R529C | Missense Mutation (SNP) | VAF 165/165 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs767303949, COSV52013022; called by muse, mutect2, varscan2
- KIAA0408 | c.1649G>A p.R550H | Missense Mutation (SNP) | VAF 216/216 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1306693969; called by muse, varscan2
- KIR3DL1 | c.1265C>T p.P422L | Missense Mutation (SNP) | VAF 268/741 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs1386977581; called by muse, mutect2
- MAP2 | c.4720C>T p.R1574W | Missense Mutation (SNP) | VAF 128/238 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758141796, COSV52301445; called by muse, mutect2, varscan2
- NIBAN3 | c.1748G>A p.R583K | Missense Mutation (SNP) | VAF 113/233 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs563812971; called by muse, mutect2, varscan2
- NUBPL | c.124A>G p.S42G | Missense Mutation (SNP) | VAF 67/252 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs771470388; called by muse, mutect2, varscan2
- OPRL1 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 376/780 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs767753848, COSV61093156; called by muse, varscan2
- PAOX | c.547G>A p.V183I | Missense Mutation (SNP) | VAF 236/442 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1402242327, COSV53371471, COSV53372036; called by muse, mutect2, varscan2
- PDZD3 | c.1054C>T p.R352C (on ENST00000531114; = p.R272C on NM_024791.4) | Missense Mutation (SNP) | VAF 125/308 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs530541915; called by muse, mutect2, varscan2
- PYROXD2 | c.1669C>T p.H557Y | Missense Mutation (SNP) | VAF 119/235 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs762433337; called by muse, mutect2, varscan2
- RGS7 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 62/151 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as rs777694599; called by muse, mutect2, varscan2
- RP1 | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 247/460 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs886062989, COSV55112474; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RS1 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 312/312 reads (100%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.57); catalogued as rs745526075, COSV66107349; called by muse, mutect2, varscan2
- SEMA3E | c.1898T>A p.V633D | Missense Mutation (SNP) | VAF 126/270 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as COSV57092455; called by muse, mutect2, varscan2
- ST6GAL2 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 301/649 reads (46%) | PolyPhen benign (0.003); catalogued as rs1260390177, COSV64532749; called by muse, mutect2, varscan2
- STEAP1B | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 164/346 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101303766, COSV101303809; called by muse, mutect2
- TESPA1 | c.1523G>A p.R508K (on ENST00000316577 / NM_001098815.3; = p.R370K on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/457 reads (19%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); catalogued as rs1365610984; called by muse, mutect2, varscan2
- ZNF335 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 318/682 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as rs1258156157; called by muse, mutect2
- ZSCAN29 | c.1508A>G p.N503S | Missense Mutation (SNP) | VAF 211/437 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147749773; called by muse, mutect2, varscan2
- ADAM33 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 260/534 reads (49%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C6orf58 | c.401T>G p.F134C | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- CCER2 | c.166C>A p.P56T | Missense Mutation (SNP) | VAF 131/605 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CDH12 | c.1558G>T p.A520S | Missense Mutation (SNP) | VAF 72/293 reads (25%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- CDKN2A | c.284_285dup p.V96Wfs*51 | Frame Shift Ins (INS) | VAF 314/431 reads (73%) | called by mutect2, pindel, varscan2
- CNKSR1 | c.20G>T p.W7L | Missense Mutation (SNP) | VAF 157/341 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL12A1 | c.6296A>T p.Y2099F | Missense Mutation (SNP) | VAF 11/266 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CUL2 | c.1668A>C p.L556F | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by muse, varscan2
- FAAH2 | c.636C>A p.C212* | Nonsense Mutation (SNP) | VAF 126/209 reads (60%) | called by muse, mutect2, varscan2
- HINFP | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 199/450 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- HMGB4 | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 242/498 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL1F10 | c.449A>G p.Q150R | Missense Mutation (SNP) | VAF 113/235 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- KCNN2 | c.1690A>T p.R564W (on ENST00000264773; = p.R776W on NM_021614.4) | Missense Mutation (SNP) | VAF 119/433 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- KIAA1109 | c.11631del p.G3878Efs*4 | Frame Shift Del (DEL) | VAF 70/174 reads (40%) | called by mutect2, pindel, varscan2
- KLHL25 | c.540G>T p.R180S | Missense Mutation (SNP) | VAF 92/545 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NELFB | c.1632G>T p.R544S | Missense Mutation (SNP) | VAF 56/411 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PASK | c.1472A>C p.N491T | Missense Mutation (SNP) | VAF 83/180 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDE3A | c.712C>A p.P238T | Missense Mutation (SNP) | VAF 71/455 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLXNB2 | c.3745T>C p.C1249R | Missense Mutation (SNP) | VAF 150/150 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- QSER1 | c.4384A>G p.S1462G (on ENST00000399302; = p.S1591G on NM_001076786.3) | Missense Mutation (SNP) | VAF 85/222 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- RFX1 | c.1432G>A p.A478T | Missense Mutation (SNP) | VAF 238/461 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RNF139 | c.613A>T p.T205S | Missense Mutation (SNP) | VAF 30/225 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SCYL3 | c.577T>C p.S193P | Missense Mutation (SNP) | VAF 53/285 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- SHANK1 | c.3176C>T p.P1059L | Missense Mutation (SNP) | VAF 306/841 reads (36%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHROOM1 | c.2275G>A p.A759T (on ENST00000378679 / NM_001172700.2; = p.A754T on NM_133456.2) | Missense Mutation (SNP) | VAF 100/513 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SLC2A12 | c.250A>T p.S84C | Missense Mutation (SNP) | VAF 127/214 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMAD4 | c.654dup p.V219Cfs*16 | Frame Shift Ins (INS) | VAF 122/173 reads (71%) | called by mutect2, pindel, varscan2
- TNR | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 197/415 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- TUBB6 | c.1178C>G p.A393G | Missense Mutation (SNP) | VAF 193/435 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- UCK1 | c.116T>C p.V39A | Missense Mutation (SNP) | VAF 366/662 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- ZYG11A | c.1166T>A p.M389K | Missense Mutation (SNP) | VAF 18/367 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- AHNAK2 | c.11229C>T p.I3743= | Silent (SNP) | VAF 55/646 reads (9%) | catalogued as rs1432864806; called by muse, mutect2
- AIMP2 | c.355C>T p.L119= | Silent (SNP) | VAF 103/379 reads (27%) | called by muse, mutect2, varscan2
- CNTN4 | c.438G>A p.P146= | Silent (SNP) | VAF 148/376 reads (39%) | catalogued as rs1281255689, COSV68563395; called by muse, mutect2, varscan2
- CORO1C | c.801G>A p.G267= | Silent (SNP) | VAF 45/334 reads (13%) | called by muse, mutect2, varscan2
- DAGLB | c.717C>T p.L239= | Silent (SNP) | VAF 186/350 reads (53%) | catalogued as rs751467052, COSV51706478; called by muse, mutect2, varscan2
- DNM1L | c.1086T>C p.G362= | Silent (SNP) | VAF 66/149 reads (44%) | called by muse, mutect2, varscan2
- DSCAML1 | c.6123C>T p.A2041= (on ENST00000321322; = p.A1981= on NM_020693.4) | Silent (SNP) | VAF 132/300 reads (44%) | catalogued as rs558725278; called by muse, mutect2, varscan2
- INSRR | c.3414G>A p.R1138= | Silent (SNP) | VAF 92/325 reads (28%) | called by muse, mutect2, varscan2
- KRTAP2-3 | c.231C>A p.I77= | Silent (SNP) | VAF 153/377 reads (41%) | called by muse, mutect2, varscan2
- LRRC45 | c.69C>A p.V23= | Silent (SNP) | VAF 351/351 reads (100%) | called by muse, mutect2, varscan2
- MROH1 | c.1182C>T p.S394= | Silent (SNP) | VAF 169/336 reads (50%) | called by muse, mutect2, varscan2
- NPAS3 | c.1452C>T p.D484= (on ENST00000356141 / NM_001164749.2; = p.D452= on NM_022123.3) | Silent (SNP) | VAF 87/289 reads (30%) | catalogued as rs778705946, COSV60835540; called by muse, mutect2, varscan2
- NTF3 | c.762C>T p.I254= | Silent (SNP) | VAF 123/208 reads (59%) | catalogued as rs201630054, COSV58417125; called by muse, mutect2, varscan2
- OR2F1 | c.681G>A p.K227= | Silent (SNP) | VAF 61/302 reads (20%) | called by muse, mutect2
- RGS7 | c.585G>A p.A195= | Silent (SNP) | VAF 169/371 reads (46%) | catalogued as rs747717735; called by muse, mutect2, varscan2
- SEC61A2 | c.681C>T p.V227= | Silent (SNP) | VAF 12/374 reads (3%) | called by muse, mutect2
- SIM2 | c.502T>C p.L168= | Silent (SNP) | VAF 111/391 reads (28%) | called by muse, mutect2, varscan2
- TRIM63 | c.246G>A p.V82= | Silent (SNP) | VAF 224/440 reads (51%) | called by muse, mutect2, varscan2
- UQCRC2 | c.102A>G p.Q34= | Silent (SNP) | VAF 162/237 reads (68%) | called by muse, mutect2, varscan2
- CC2D2B | c.780+5032G>A | Intron (SNP) | VAF 39/90 reads (43%) | called by muse, mutect2, varscan2
- DCHS2 | n.4063C>A | RNA (SNP) | VAF 127/127 reads (100%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+4773G>C | Intron (SNP) | VAF 173/349 reads (50%) | called by muse, mutect2, varscan2
- MAP3K20 | c.987+4100G>A | Intron (SNP) | VAF 141/492 reads (29%) | called by muse, varscan2
- SLC30A2 | c.271+652C>A | Intron (SNP) | VAF 46/508 reads (9%) | catalogued as COSV100958509; called by muse, mutect2
- TTN | c.34265-3935G>T | Intron (SNP) | VAF 92/436 reads (21%) | catalogued as COSV100612107; called by muse, varscan2
